Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACN, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACN-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : Liver

Gross Photo : 1

GROSS:

Specimen:

Liver: 14.0 x 9.0 x 6.0 cm, unfixed

Tumor location: segment 6

Tumor number: one

Tumor size: 3.5 x 2.8 x 2.5 cm

Satellite nodule: no

Gross type

HCC: expanding nodular

Tumor necrosis: less than 5 %

Hemorrhage/peliosis: no

Portal vein invasion: no

Bile duct invasion: no

Safety margin: 1.8 cm

ICD-O-3
Carcinoma, hepatocellular NOS
Site: Liver C22.0
817013
JW 5/19/14

Gross photo present.

Blocks

T1-4, tumor and surrounding parenchyme of liver x 4

L, nontumorous liver parenchyme x 1

RM, resection margin of liver x 1

MICROSCOPIC:

Hepatocellular carcinoma, with cholangiocytic differentiation

Differentiation

The worst differentiation III

The major differentiation III

Histologic type: trabecular

Cell type: hepatic

Other tumor: no

Fibrous capsule formation: no

Capsular infiltration: no

Septum formation: no

Surgical resection margin invasion: no

Serosal invasion: no

Portal vein invasion: no

Bile duct invasion: no

Hepatic vein invasion: no

Hepatic artery invasion: no

Microvessel invasion: no

Per TSS ? cholangiocytic unknown.

[page 2 of 2]
Intrahepatic metastasis: no
Multicentric occurrence: no

Non-tumor liver pathology

Chronic hepatitis: yes
Etiology: HBV
Grade, lobular: I
Grade, portoperiportal: II
Stage (fibrosis): I
Cirrhosis: no
Dysplastic nodule: no
Ductal epithelial dysplasia: no
Other liver diseases:
Fatty change: 60 %

SPECIAL STAIN: Mucicarmin (-)

IMMUNOHISTOCHEMISTRY:

CK7 (+ , focal), CK (+), CK19 (+ , focal), AFP (-), Hepatocyte (+)

NOT reported. Gross:

Disc material, ectomy, degenerated fibrocartilagenous tissue

Liver, ectomy, hepatocellular carcinoma, chronic hepatitis, steatosis
T56000, P10, M81703, MD0522, M50080

DIAGNOSIS:

Liver, segment 6, right posterior sectionectomy:
Hepatocellular carcinoma, poorly differentiated,
with cholangiocytic differentiation
Chronic hepatitis, associated HBV
Steatosis, moderate

NOTE:

(mucicarmin) (CK7, CK, CK19, AFP, Hepatocyte)

Suggestion :

OK to process

Source: NCI Genomic Data Commons file 1e4dacf0-e213-4057-8251-bdd561ceb5d0 (TCGA-DD-AACN.449B3C67-3530-4728-9F38-F44F4D8EC027.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).